CCDI case PBBRGM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/9f2ab257-c8ed-4db8-b773-32600da60274

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.2 years (1,889 days).

Biospecimens (3 samples)
- Sample 0DF02V: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF02W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DF02Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
